Somatic mutation profile of tumor specimen TCGA-D9-A4Z2-01A (aliquot TCGA-D9-A4Z2-01A-11D-A24R-08) from TCGA case TCGA-D9-A4Z2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.6 years (18,469 days).
Specimen TCGA-D9-A4Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94a2bd48-2eb3-4c71-a5e4-63aed51a6aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A4Z2-10A (Blood Derived Normal), aliquot TCGA-D9-A4Z2-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/316b1674-a58a-4a46-b039-306790c5bbc6

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADRA1D | c.1106C>G p.P369R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437404692, COSV65241470; called by muse, mutect2, varscan2
- AJAP1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1362035936, COSV65452111; called by muse, mutect2, varscan2
- ARHGAP22 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50958216; called by muse, mutect2, varscan2
- CTTN | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV57234113; called by muse, mutect2
- DIP2C | c.2944A>G p.T982A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV55168035; called by muse, mutect2, varscan2
- DSCAM | c.3135C>A p.D1045E | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV68031306; called by muse, mutect2
- ERI3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV64830175; called by muse, mutect2
- KCNQ5 | c.1763A>T p.E588V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV59671104; called by muse, mutect2, varscan2
- KDM3A | c.3305A>C p.N1102T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV57223488; called by muse, mutect2, varscan2
- MAP2K2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607230, CM071854, CM101871, COSV53567689, COSV53569132; called by muse, mutect2, varscan2
- NPTX2 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV55718120; called by muse, mutect2
- PCLO | c.4081A>T p.S1361C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV61649473; called by muse, mutect2, varscan2
- PDCL3 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51809740; called by muse, mutect2
- SND1 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 53/173 reads (31%) | catalogued as COSV61244782; called by muse, mutect2, varscan2
- SRSF2 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57974021; called by muse, mutect2, varscan2
- TBX1 | c.814G>C p.A272P | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60354628; called by muse, mutect2, varscan2
- TMPRSS4 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV71109770; called by muse, mutect2, varscan2
- ZNF438 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 87/116 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59197940; called by muse, mutect2, varscan2
- DNAAF5 | c.2199C>T p.G733= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as rs1188920913, COSV52419113; called by muse, mutect2
- FLNB | c.6540C>T p.P2180= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV55886483; called by muse, mutect2, varscan2
- GGA3 | c.2127C>T p.G709= (on ENST00000537686 / NM_138619.4; = p.G676= on NM_014001.5) | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs772900672, COSV55457697; called by muse, mutect2, varscan2
- GSX2 | c.843C>T p.Y281= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs146677175, COSV58843114; called by muse, mutect2
- MAGI2 | c.879T>G p.T293= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV62679678; called by muse, mutect2
- TBP | c.234G>A p.Q78= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs113440919, COSV57830415; called by muse, varscan2
- ATP2B1 | c.3351+405G>A | Intron (SNP) | VAF 88/204 reads (43%) | catalogued as COSV99665187; called by muse, varscan2
